Somatic mutation profile of tumor specimen MMRF_2126_2_BM_CD138pos (aliquot MMRF_2126_2_BM_CD138pos_T1_KHS5U_L14860) from MMRF case MMRF_2126, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.0 years (25,948 days).
Specimen MMRF_2126_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f4847b0-3e4c-4bf5-80e2-caa0fb93ce8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2126_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2126_1_PB_Whole_C2_KHS5U_L08681; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a11ac3d-bb3f-4690-b7e7-3a4c454e34df

The open-access MAF lists 160 somatic variants for this specimen: 75 protein-altering or splice-affecting, 17 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, 3'UTR 38, Silent 17, Intron 15, 5'UTR 7, Nonsense Mutation 6, RNA 4, In Frame Del 4, 5'Flank 3, Splice Region 1, Frame Shift Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 50/104 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ADAMTS17 | c.1520C>A p.S507Y | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as rs779332890; called by muse, mutect2, varscan2
- AGRN | c.2950G>A p.V984M | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs371483148; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.2639C>G p.T880R (on ENST00000280772 / NM_001320874.2; = p.T14R on NM_001149.3) | Missense Mutation (SNP) | VAF 163/342 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV55077518; called by muse, mutect2, varscan2
- ARHGAP21 | c.5362G>A p.V1788M | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs566025075; called by muse, mutect2, varscan2
- ATXN7L1 | c.1050_1055del p.D350_K351del | In Frame Del (DEL) | VAF 28/73 reads (38%) | catalogued as rs1171185094; called by pindel, varscan2
- CCL11 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 105/223 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.41); catalogued as rs1429491045, COSV59925555; called by muse, mutect2, varscan2
- CTBP1 | c.923C>G p.P308R | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV52072348; called by muse, mutect2, varscan2
- CUBN | c.6181C>T p.P2061S | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.794); catalogued as rs755994153; called by muse, mutect2, varscan2
- FOXA3 | c.800A>G p.D267G | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as rs1004526212; called by muse, mutect2, varscan2
- HJURP | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | catalogued as COSV68578823; called by muse, mutect2, varscan2
- IGLV3-25 | c.162C>G p.Y54* | Nonsense Mutation (SNP) | VAF 58/151 reads (38%) | catalogued as rs369844361; called by muse, mutect2, varscan2
- IQCN | c.3388C>T p.R1130C | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs192651551; called by muse, mutect2, varscan2
- KCTD15 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs750587104, COSV52290801; called by muse, mutect2
- LHCGR | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1352747382, COSV54301629; called by muse, mutect2, varscan2
- LRIG3 | c.3119C>T p.T1040I | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1412100626; called by muse, mutect2, varscan2
- MAZ | c.39dup p.F14Lfs*34 | Frame Shift Ins (INS) | VAF 22/50 reads (44%) | catalogued as rs767720617; called by mutect2, varscan2
- MYBPC3 | c.2449C>G p.R817G | Missense Mutation (SNP) | VAF 101/348 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM160559, COSV57022934; called by muse, mutect2, varscan2
- PCDHA3 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 24/49 reads (49%) | catalogued as COSV65366052; called by muse, mutect2, varscan2
- PCDHA7 | c.1919C>T p.T640M | Missense Mutation (SNP) | VAF 82/189 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.109); catalogued as rs781952009, COSV65342627; called by muse, mutect2, varscan2
- PPRC1 | c.4376C>T p.S1459F | Missense Mutation (SNP) | VAF 105/193 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.718); catalogued as COSV53386648; called by muse, mutect2, varscan2
- PTCHD4 | c.1935del p.S646Pfs*17 | Frame Shift Del (DEL) | VAF 40/93 reads (43%) | catalogued as COSV59780910; called by mutect2, pindel, varscan2
- RARS1 | c.908A>G p.D303G | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as rs1378012147; called by muse, mutect2, varscan2
- SEMA4B | c.1154A>G p.Y385C | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1229823650; called by muse, mutect2, varscan2
- SHANK1 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1459706968, COSV53241893; called by muse, mutect2, varscan2
- SHOX | c.327G>C p.E109D | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs746842667; called by muse, mutect2, varscan2
- TTC38 | c.1286G>A p.C429Y | Missense Mutation (SNP) | VAF 95/226 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as rs538848788; called by muse, mutect2, varscan2
- UNC5D | c.1737T>G p.I579M | Missense Mutation (SNP) | VAF 65/142 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1164767676; called by muse, mutect2, varscan2
- ZC3H6 | c.2515A>G p.I839V | Missense Mutation (SNP) | VAF 110/207 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs764308507; called by muse, mutect2, varscan2
- ACADM | c.1117G>A p.V373M | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- AMOTL2 | c.778_783del p.Q260_Q261del | In Frame Del (DEL) | VAF 26/78 reads (33%) | called by mutect2, pindel, varscan2
- AREG | c.728A>C p.Q243P | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ASAP3 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- C1QTNF4 | c.891C>A p.Y297* | Nonsense Mutation (SNP) | VAF 77/245 reads (31%) | called by muse, mutect2, varscan2
- CD2AP | c.185A>T p.E62V | Missense Mutation (SNP) | VAF 92/180 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- CHD1 | c.51A>T p.S17= | Splice Region (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- CNTROB | c.2683A>C p.M895L | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- COLGALT1 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- DDHD1 | c.1637G>A p.G546D (on ENST00000323669; = p.G743D on NM_030637.3) | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- EFL1 | c.1148A>C p.Q383P | Missense Mutation (SNP) | VAF 63/315 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- EGR1 | c.990G>T p.K330N | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EIF2S3B | c.509C>G p.T170R | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- GRIK1 | c.2130G>T p.K710N | Missense Mutation (SNP) | VAF 108/159 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GTF2A1 | c.18T>G p.N6K | Missense Mutation (SNP) | VAF 143/308 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GUCA1A | c.72G>T p.K24N | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- H4C12 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ICE2 | c.2903A>G p.Q968R | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.328); called by muse, mutect2
- IGHV2-70D | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); called by muse, varscan2
- IGHV2-70D | c.227A>C p.D76A | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- IGHV2-70D | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 62/106 reads (58%) | SIFT tolerated (0.48); PolyPhen benign (0.194); called by muse, varscan2
- IGHV2-70D | c.124A>T p.T42S | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.087); called by muse, varscan2
- IGHV2-70D | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.376); called by muse, varscan2
- ITGA9 | c.2171T>G p.I724S | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- KHDC1 | c.313C>T p.Q105* (on ENST00000370384 / NM_001251874.2; = p.Q32* on NM_030568.5) | Nonsense Mutation (SNP) | VAF 46/92 reads (50%) | called by muse, mutect2, varscan2
- LMLN | c.1965C>A p.H655Q | Missense Mutation (SNP) | VAF 87/365 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- LRRC32 | c.1668G>A p.M556I | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- OR2AG2 | c.200C>G p.S67C | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2
- OR2G2 | c.484C>A p.Q162K | Missense Mutation (SNP) | VAF 60/178 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- OR5AS1 | c.260C>A p.A87E | Missense Mutation (SNP) | VAF 12/323 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); called by muse, mutect2
- PAXIP1 | c.3209G>T p.*1070Lext*49 | Nonstop Mutation (SNP) | VAF 60/159 reads (38%) | called by muse, mutect2, varscan2
- PDPR | c.715A>T p.N239Y | Missense Mutation (SNP) | VAF 47/347 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PHLPP1 | c.33_38del p.L12_P13del | In Frame Del (DEL) | VAF 22/47 reads (47%) | called by mutect2, pindel, varscan2
- PNLIP | c.1129T>G p.F377V | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- POU2F1 | c.1997G>C p.G666A (on ENST00000541643 / NM_001365848.1; = p.G689A on NM_002697.4) | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- PPP1R3A | c.1595A>C p.K532T | Missense Mutation (SNP) | VAF 67/123 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- RMC1 | c.17A>T p.Y6F | Missense Mutation (SNP) | VAF 64/140 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, varscan2
- SLC17A1 | c.1078T>C p.S360P | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- SLCO2B1 | c.1286G>A p.G429D | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SNX33 | c.659G>A p.G220D | Missense Mutation (SNP) | VAF 38/390 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRAT1 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- TTLL12 | c.689G>T p.R230M | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- TTN | c.4453A>T p.M1485L (on ENST00000591111; = p.M1439L on NM_003319.4) | Missense Mutation (SNP) | VAF 73/148 reads (49%) | PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- TXNDC11 | c.1903_1929del p.F635_E643del (on ENST00000356957 / NM_001303447.2; = p.F608_E616del on NM_015914.7 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 30/149 reads (20%) | called by mutect2, varscan2
- USP7 | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VCPIP1 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 75/163 reads (46%) | called by muse, mutect2, varscan2
- BPTF | c.471T>C p.D157= | Silent (SNP) | VAF 27/57 reads (47%) | called by muse, mutect2, varscan2
- CAMSAP3 | c.3528G>A p.S1176= | Silent (SNP) | VAF 78/221 reads (35%) | catalogued as rs1347908775; called by muse, mutect2, varscan2
- CRYBG1 | c.2457G>A p.E819= | Silent (SNP) | VAF 60/137 reads (44%) | called by muse, mutect2, varscan2
- HTRA1 | c.222C>A p.A74= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs1258751091; called by muse, mutect2, varscan2
- IGHV2-70D | c.96A>G p.K32= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs1326050117; called by muse, varscan2
- MACF1 | c.165G>A p.R55= | Silent (SNP) | VAF 88/172 reads (51%) | catalogued as rs1258080952; called by muse, mutect2, varscan2
- OBSL1 | c.897C>T p.D299= | Silent (SNP) | VAF 162/319 reads (51%) | catalogued as COSV99216931; called by muse, varscan2
- OLFML2A | c.711C>G p.G237= | Silent (SNP) | VAF 29/159 reads (18%) | called by muse, mutect2, varscan2
- PKD2 | c.2769C>A p.S923= | Silent (SNP) | VAF 47/99 reads (47%) | called by muse, mutect2, varscan2
- SIGLEC9 | c.1035G>C p.V345= | Silent (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- SLIT2 | c.1845C>T p.S615= | Silent (SNP) | VAF 63/144 reads (44%) | called by muse, mutect2, varscan2
- SLIT3 | c.159C>T p.R53= | Silent (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- TEDC1 | c.855G>A p.G285= | Silent (SNP) | VAF 42/77 reads (55%) | catalogued as rs1485157632; called by muse, mutect2, varscan2
- TLN1 | c.2115A>C p.A705= | Silent (SNP) | VAF 11/105 reads (10%) | called by muse, mutect2
- TUBA3E | c.1287G>A p.E429= | Silent (SNP) | VAF 78/150 reads (52%) | called by muse, mutect2, varscan2
- USP47 | c.2331C>T p.S777= (on ENST00000399455 / NM_001372095.1; = p.S689= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 61/243 reads (25%) | called by muse, mutect2, varscan2
- ZNF665 | c.75A>G p.E25= (on ENST00000600412; = p.E90= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 30/185 reads (16%) | called by muse, mutect2, varscan2
- ABI2 | c.*2518C>T | 3'UTR (SNP) | VAF 47/97 reads (48%) | catalogued as rs192710243; called by muse, mutect2, varscan2
- ACP2 | c.114+83G>C | Intron (SNP) | VAF 50/157 reads (32%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.*629C>A | 3'UTR (SNP) | VAF 62/166 reads (37%) | called by muse, mutect2, varscan2
- ADGRV1 | c.*25C>T | 3'UTR (SNP) | VAF 105/235 reads (45%) | called by muse, mutect2, varscan2
- AGO4 | c.*1238C>A | 3'UTR (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- ANGPTL8 | c.*101G>A | 3'UTR (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.*1936T>C | 3'UTR (SNP) | VAF 47/102 reads (46%) | called by muse, mutect2, varscan2
- ARSJ | c.*154C>T | 3'UTR (SNP) | VAF 55/105 reads (52%) | catalogued as rs974551039; called by muse, mutect2, varscan2
- ATXN2L | c.465+22dup | Intron (INS) | VAF 24/69 reads (35%) | called by mutect2, pindel, varscan2
- C12orf73 | c.-10-51G>C | Intron (SNP) | VAF 27/86 reads (31%) | called by muse, mutect2, varscan2
- C14orf180 | chr14:104590341 C>A | 3'Flank (SNP) | VAF 19/132 reads (14%) | called by muse, mutect2, varscan2
- C14orf28 | c.*360G>A | 3'UTR (SNP) | VAF 25/48 reads (52%) | catalogued as rs576819082; called by muse, mutect2, varscan2
- CALN1 | c.*987G>T | 3'UTR (SNP) | VAF 20/94 reads (21%) | called by muse, mutect2, varscan2
- CALU | c.*1347C>T | 3'UTR (SNP) | VAF 43/92 reads (47%) | called by muse, mutect2, varscan2
- CCDC33 | c.2140-313C>A | Intron (SNP) | VAF 91/370 reads (25%) | called by muse, mutect2, varscan2
- CD163L1 | c.124+1818G>A | Intron (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- CD48 | c.385+539T>G | Intron (SNP) | VAF 17/137 reads (12%) | called by muse, mutect2, varscan2
- CLN5 | c.565+17T>G | Intron (SNP) | VAF 60/111 reads (54%) | called by muse, mutect2, varscan2
- CNOT6 | c.*174T>C | 3'UTR (SNP) | VAF 18/26 reads (69%) | called by muse, varscan2
- COL5A2 | c.*88G>T | 3'UTR (SNP) | VAF 17/35 reads (49%) | called by muse, mutect2, varscan2
- CUX1 | c.*7713T>C | 3'UTR (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- CXCL12 | c.*2710T>A | 3'UTR (SNP) | VAF 32/68 reads (47%) | catalogued as rs959532031; called by muse, mutect2, varscan2
- CYP19A1 | c.*1447C>A | 3'UTR (SNP) | VAF 29/155 reads (19%) | called by muse, mutect2, varscan2
- DPP10 | c.441+110_441+111del | Intron (DEL) | VAF 15/33 reads (45%) | called by mutect2, pindel, varscan2
- ECHDC1 | c.-390dup | 5'UTR (INS) | VAF 33/84 reads (39%) | called by mutect2, pindel, varscan2
- EFEMP2 | c.111+18C>T | Intron (SNP) | VAF 36/148 reads (24%) | catalogued as rs777429558; called by muse, varscan2
- ELAVL2 | c.*477T>A | 3'UTR (SNP) | VAF 44/73 reads (60%) | called by muse, mutect2, varscan2
- FAM131A | c.*25T>C | 3'UTR (SNP) | VAF 36/140 reads (26%) | catalogued as rs760991776; called by muse, mutect2
- FAM207A | c.*145C>A | 3'UTR (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- FAM217A | c.-94C>A | 5'UTR (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- GABRE | c.784+1360C>T | Intron (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- GALNT9 | c.1077+208G>A | Intron (SNP) | VAF 20/43 reads (47%) | catalogued as rs552474801; called by muse, mutect2, varscan2
- H4C9 | c.-153A>T | 5'UTR (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- HEG1 | c.*1515G>A | 3'UTR (SNP) | VAF 34/106 reads (32%) | catalogued as rs1187682060; called by muse, mutect2, varscan2
- HSP90AA4P | n.976G>C | RNA (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- KAT6A | c.*385C>T | 3'UTR (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- KCTD10 | c.527+141G>T | Intron (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- KLHL15 | c.*1385T>G | 3'UTR (SNP) | VAF 26/28 reads (93%) | called by muse, mutect2, varscan2
- KRT23 | c.-265G>A | 5'UTR (SNP) | VAF 29/96 reads (30%) | called by muse, mutect2, varscan2
- LINC00632 | n.104+2616T>G | Intron (SNP) | VAF 181/184 reads (98%) | called by muse, mutect2, varscan2
- MASTL | chr10:27155337 C>A | 5'Flank (SNP) | VAF 16/24 reads (67%) | called by muse, mutect2, varscan2
- MIR873 | n.33T>C | RNA (SNP) | VAF 84/137 reads (61%) | catalogued as rs1327059722; called by muse, mutect2, varscan2
- MSL2 | c.-509del | 5'UTR (DEL) | VAF 64/258 reads (25%) | called by pindel, varscan2
- NEBL-AS1 | chr10:21173851 G>A | 5'Flank (SNP) | VAF 53/123 reads (43%) | catalogued as rs758297245; called by muse, mutect2, varscan2
- NRIP3 | c.*1866C>T | 3'UTR (SNP) | VAF 37/89 reads (42%) | called by muse, mutect2, varscan2
- OR10C1 | chr6:29439456 A>G | 5'Flank (SNP) | VAF 15/28 reads (54%) | called by muse, mutect2, varscan2
- OR10J8P | n.127G>A | RNA (SNP) | VAF 159/253 reads (63%) | called by muse, mutect2, varscan2
- PCDH11Y | c.*3460dup | 3'UTR (INS) | VAF 102/121 reads (84%) | called by mutect2, varscan2
- PCDH17 | c.*3324A>G | 3'UTR (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2, varscan2
- PDE3A | c.-64G>A | 5'UTR (SNP) | VAF 10/17 reads (59%) | called by muse, mutect2, varscan2
- PDZRN4 | c.*458G>A | 3'UTR (SNP) | VAF 33/35 reads (94%) | called by muse, mutect2, varscan2
- PHTF1 | c.-236del | 5'UTR (DEL) | VAF 8/13 reads (62%) | called by mutect2, varscan2
- PIP4P1 | c.*405T>C | 3'UTR (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- RAB37 | c.*1688C>T | 3'UTR (SNP) | VAF 50/103 reads (49%) | called by muse, mutect2, varscan2
- RBFA | c.*3056T>A | 3'UTR (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- RNF166 | c.*984C>T | 3'UTR (SNP) | VAF 274/286 reads (96%) | catalogued as rs370754723; called by muse, varscan2
- SERPINB8 | c.*1900C>T | 3'UTR (SNP) | VAF 34/72 reads (47%) | called by muse, mutect2, varscan2
- SLC25A13 | c.*147A>G | 3'UTR (SNP) | VAF 38/76 reads (50%) | catalogued as rs897852072; called by muse, mutect2, varscan2
- SLC5A12 | c.*1451G>A | 3'UTR (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- SLC8A3 | c.*1514del | 3'UTR (DEL) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- SOX1 | c.*1669C>T | 3'UTR (SNP) | VAF 16/74 reads (22%) | catalogued as rs909382108; called by muse, mutect2, varscan2
- SP3 | c.*1475T>C | 3'UTR (SNP) | VAF 48/111 reads (43%) | called by muse, mutect2, varscan2
- TADA2B | c.*40T>A | 3'UTR (SNP) | VAF 99/206 reads (48%) | called by muse, mutect2, varscan2
- TLK1 | c.*1195A>G | 3'UTR (SNP) | VAF 37/78 reads (47%) | called by muse, mutect2, varscan2
- TRIM61 | c.526-2858G>T | Intron (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- XAB2 | c.1618-39T>C | Intron (SNP) | VAF 24/176 reads (14%) | called by muse, mutect2, varscan2
- ZDHHC14 | c.*761C>A | 3'UTR (SNP) | VAF 81/167 reads (49%) | called by muse, mutect2, varscan2
- ZNF286B | n.1818_1823del | RNA (DEL) | VAF 53/139 reads (38%) | called by mutect2, varscan2
